Surgical pathology report (de-identified scan), TCGA case TCGA-29-1762, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Duke, specimen TCGA-29-1762-01A (Primary Tumor).

[page 1 of 2]
Surg Path

TCGA-29-1762

CLINICAL HISTORY:

with ovarian carcinoma, malignant effusion and ascites.

GROSS EXAMINATION:

A. "Right ovary (AF1)", received fresh. A 162 gram, 12.2 x 9.5 x 3.8 cm aggregate of lobulated, friable, gray-tan tissue with focally adherent blood clot. Representative tissue is frozen as AF1. The remnant is submitted as A1. Additional sections submitted as A2-3.

B. "Uterus" (gross consult), received fresh. A 75.4 gram, 7.5 x 4.5 x 3.8 cm uterus with an attached 3.5 x 2.4 cm cervix and attached 5.8 x 0.6 cm right fallopian tube. The serosa is markedly roughened with multiple fibrous adhesions and focally discolored green, tan. The ectocervix is smooth, gray-white and glistening with a central patent 1.4 cm os extending into a trabecular yellow endocervical canal. The endometrium is granular, gray-tan and less than 0.1 cm in uniform thickness. The myometrium is 1.4 cm in thickness and contains two intramural white circumscribed nodules each 0.8 cm in diameter. Sectioning of the fallopian tube reveals a patent lumen and abundant hemorrhage in the adjacent peritubular soft tissue.

Block Summary:

B1-2 Anterior and posterior cervix, respectively.

B3-4 Anterior and posterior endometrium respectively.

B5 Right fallopian tube.

Also received is a 5.9 x 4.5 x 2.6 cm aggregate of granular gray-tan tissue from which representative sections are submitted as B6.

C. "Omentum", received fresh. Four fragments of finely lobulated yellow-pink adipose aggregating 14.5 x 11.5 x 0.6 cm. No discrete lesions or nodules are noted. Representative sections are submitted as C1 and C2.

Each fragment is sampled.

D. "Left tube and ovary", received fresh. A 16.7 gram aggregate of tissue composed of a 4.5 x 0.5 cm segment of fallopian tube adjacent to a nodular and slightly distorted 3.7 x 1.8 x 1.5 cm ovary. The serosa is markedly granular and studded with small friable nodules. Sectioning the tube reveals a patent lumen. Sectioning of the ovary reveals a yellow-white fibrous cut surface. Representative sections from the ovary are submitted as D1 and from the tube as D2.

E. "Bladder flap tumor", received fresh. A 7.5 x 4.4 x 2.2 cm aggregate of soft, friable, pink-tan tissue from representative sections are submitted as E1 and E2.

INTRA OPERATIVE CONSULTATION:

A. "Right ovary": AF1- adenocarcinoma

B. "Uterus" (gross consult) - no evidence of endometrial carcinoma

DIAGNOSIS:

A. "RIGHT OVARY" (OOPHORECTOMY):

SEROUS CARCINOMA OF OVARY, MODERATELY DIFFERENTIATED (GRADE 2 OF 3).

[page 2 of 2]
TUMOR SIZE: 12.2 CM (AGGREGATE MEASUREMENT).

TCGA-29-1762

B. "UTERUS" (HYSTERECTOMY AND RIGHT SALPINGECTOMY):

UTERUS (75.4 GM) WITH:

METASTATIC SEROUS CARCINOMA TO SEROSA.

CERVIX, NO PATHOLOGIC DIAGNOSIS.

ENDOMETRIUM, INACTIVE.

MYOMETRIUM, WITH TWO LEIOMYOMAS (GREATEST SINGLE DIMENSION 0.8 CM).

RIGHT FALLOPIAN TUBE WITH METASTATIC SEROUS CARCINOMA.

C. "OMENTUM" (BIOPSY):

OMENTUM WITH METASTATIC SEROUS CARCINOMA.

D. "LEFT TUBE AND OVARY" (SALPINGO-OOPHORECTOMY):

LEFT OVARY AND FALLOPIAN TUBE WITH METASTATIC SEROUS CARCINOMA.

E. "BLADDER FLAP TUMOR":

METASTATIC SEROUS CARCINOMA.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file bf3382eb-d0b7-4f10-a833-24affcb9e488 (TCGA-29-1762.F94712A1-78DA-4341-9AC9-6EA41C11610E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).